Surgical pathology report (de-identified scan), TCGA case TCGA-B6-A0IB, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Duke, specimen TCGA-B6-A0IB-01A (Primary Tumor).

ICD-0-3

Carcinoma, duct NOS, infiltration 8500/3

Site Code: breast, NOS C50.9

1/17/11

hw

Patient:

~~Surgical Pathology Final~~

Surg Path

CLINICAL HISTORY:

Right breast cancer.

GROSS EXAMINATION:

A. "Right breast": Received fresh is a 25 x 17 x 3.5 cm right breast and axillary tail. Attached to the breast is an 18 x 9 cm ellipse of skin containing the nipple. In the inner upper and inner lower quadrant there is a 6 x 3.5 x 3.0 cm biopsy cavity. Surrounding the biopsy cavity is firm to hard breast tissue. This tissue extends from the biopsy cavity from 1.0 x 2.5 cm in all directions. Tissue from this main tumor mass was submitted for estrogen receptors labeled as "A". Approximately 5 cm lateral to the biopsy cavity there is another nodule within the breast that measures approximately 3 cm in diameter. Tissue from this smaller mass was submitted for estrogen receptors labeled as "B". Small amounts of firm breast tissue are palpated between the main tumor mass in this second 3 cm tumor mass. It is difficult to determine whether this second tumor mass is an isolated lesion or an extension of the main tumor mass.

Block Summary:

- A1: Section adjacent to biopsy cavity containing a deep margin which has been inked blue.
A2: Section adjacent to biopsy site containing deep margin.
A3: Random section of tumor adjacent to biopsy site.
A4: Section of firm area between the biopsy cavity and the smaller mass lateral to it.
A5: Section of the 3 cm in diameter mass lateral to the biopsy cavity.
A6: Upper outer quadrant.
A7: Lower inner quadrant.
A8: Skin beneath the biopsy cavity.
A9: Nipple.
A10: Lymph nodes from the proximal 1/3 of the axillary tail.
A11: Lymph nodes from the mid 1/3 of the axillary tail.
A12: Lymph nodes from the distal 1/3 of the axillary tail.

DIAGNOSIS:

A. "RIGHT BREAST":

RIGHT BREAST STATUS POST BIOPSY FOR INVASIVE DUCTAL CARCINOMA WITH EXTENSIVE RESIDUAL INVASIVE CARCINOMA EXTENDING INTO THE DEEP DERMIS (BLOCK A8). HISTOLOGIC GRADE: III. NUCLEAR GRADE: III.

B. "LYMPH NODES":

LEVEL-I, NEGATIVE FOR CANCER, ONE EXAMINED.
LEVEL-II, LYMPH NODES POSITIVE FOR CANCER, SIX OF NINE EXAMINED.
LEVEL-III LYMPH NODES POSITIVE FOR CANCER, TWO OF FIVE EXAMINED.

ALL FINAL SURGICAL MARGINS NEGATIVE FOR CANCER.

Verified by:

(Electronic Signature,

Date Signed

Source: NCI Genomic Data Commons file 721a1662-f3fb-49b4-9455-e656270379ce (TCGA-B6-A0IB.CFC4801B-04BD-4FFC-911A-7B88E2FA4B49.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).